Surgical pathology report (de-identified scan), TCGA case TCGA-QH-A6CU, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Fondazione-Besta, specimen TCGA-QH-A6CU-01A (Primary Tumor).

OBJECT: PATHOLOGIST REPORT

Code:

Gender: F

Age:

Date of surgery:

Localisation: L frontal

Diagnosis: anaplastic oligodendroglioma (grade III WHO)

Name of Pathologist:

ICD-0-3
Oligodendroglioma, anaplastic
9451/3
Site ^{CSCF} Brain, supratentorial NOS
path ^{C71.0} Brain, frontal lobe
JW 5/16/13

Source: NCI Genomic Data Commons file ca4f2dd8-6e59-49cc-967f-1aece554af92 (TCGA-QH-A6CU.F87EBF56-A3DC-4790-98AB-1B93FB917CAC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).